TARGET case TARGET-10-PAPJHB — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/160ba08d-ae98-5467-a125-d541b39582d0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 5 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 5.5 years (2,005 days); Year of diagnosis: 2006; Days to last follow up: 1,870 days (5.1 years).
   Treatment given: Protocol identifier: AALL0331.

Follow-up (2 entries)
- Days to follow up: 1,260 days (3.4 years); Days to first event: 1,260 days (3.4 years); First event: Relapse.
- Days to follow up: 1,870 days (5.1 years); Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow; Year of follow up: 2011.

Molecular and laboratory tests (laboratory values grouped by visit day)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- TCF3–PBX1 translocation: Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 13.7 ×10³/µL.
- Day 8: Bone Marrow blast count 26%.
- Day 15: Bone Marrow blast count 3%.
- Day 29: Bone Marrow blast count 0%; Minimal Residual Disease (Flow Cytometry) 0.1%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (4 samples)
- Sample TARGET-10-PAPJHB-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPJHB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PAPJHB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TARGET-10-PAPJHB-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 1870
- WBC at Diagnosis: 13.7
- CNS Status at Diagnosis: CNS 1
- MRD Day 29: 0.1
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.1
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- TCF3 PBX1 Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 26
- BMA Blasts Day 15: 3
- BMA Blasts Day 29: 0
- Karyotype: 47,XX,add(9)(p13),+21[6]/45,idem,-X,-20[3]/48,idem,+8[7]/46,XX[4]
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
